Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A7CM, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A7CM-01A (Primary Tumor).

[page 1 of 4]
Results

SURG PATH FINAL REPORT

Service Location

Name

Address

Patient Information

Patient Name

Sex

DOB

Phone

Female

Result Notes

Notes Recorded by

Forwarded to

Status:

This result is currently not released to

Collection Information

Entry Date

Component Results

SURG PATH FINAL REPORT

ICD O-3

Adenocarcinoma, endocervical type
8584/3

Site Cervix NOS
C53.9

JW 8/27/13

Accession #:

Specimen:

Date of Procedure:

Performing Clinician: M.D.

A. Cervical biopsy

Clinical Notes:

Personal history of malignant neoplasm of cervix uteri

Cervical cancer.

Diagnosis:

A. Cervix, biopsy:

- Invasive moderately differentiated
adenocarcinoma, see comment.

COMMENT: The current specimen was compared with the previous
biopsy and shows similar histological
features.

MD

[page 2 of 4]
[REDACTED]

(Electronically signed by)
Verified: [REDACTED]

Gross:

A. The specimen is received as cervical biopsy per the requisition slip. The specimen container is labeled with the patient's name; however, the organ/tissue site is not identified on the jar. Received in formalin is a 1.0 x 1.0 x 0.3 cm aggregate of pink to red, soft tissue fragments. The specimen is submitted in toto in cassette A.

[REDACTED]

[REDACTED]

Microscopic:

A histological examination has been performed.

Administrative Notes:

CPT:

Accession #: [REDACTED]

No charge codes are associated with this case.

Result History

SURG PATH FINAL REPORT [REDACTED] on [REDACTED] Order Result History Report.

Lab Information

Resulting Agency
[REDACTED]

Lab Collection Information

Collection Date and Time
[REDACTED]

IDs

Order #
[REDACTED]

Specimen #
[REDACTED]

[REDACTED] (MR # [REDACTED]) Printed by [REDACTED]

Final Synchronous Primary noted		X
Reviewer Initials	[REDACTED]	Date Reviewed: 8/19/13

[page 3 of 4]
(MR # [REDACTED])

Results History

SURG PATH FINAL REPORT

Entry Information

Entry Date and Time

Lab Status
Final result

Entered by [REDACTED]

Component Results

SURG PATH FINAL REPORT:

Accession #: [REDACTED]

Specimen:

Date of Consult:

Requesting Physician: [REDACTED]

[REDACTED] (10 slides and 1 block)

CONSULT SLIDES: [REDACTED] / [REDACTED]

Clinical Notes:

Prolapsed fibroid. Patient appointment

Diagnosis:

CONSULT SLIDES: [REDACTED]

Consult case [REDACTED]

A. Posterior cervix at 6 o'clock, biopsy:

- Invasive and in situ endocervical adenocarcinoma, moderately differentiated, see note.

B. Endocervical mass, biopsy:

- Invasive and in situ endocervical adenocarcinoma, moderately differentiated with mucinous features, see note.

NOTE (A-B): Both specimens are similar and show glands with areas of cribriform, tubular cystic and papillary growth pattern. The cytoplasm of the tumor cells vary from pale pink to clear with some tumor cells showing large hyperchromatic and pleomorphic nuclei and scattered mitoses. Focal tumor cell necrosis is also present. Both specimens in addition show areas of in situ adenocarcinoma.

Immunohistochemical stains obtained at our institution show the tumor to be positive for p16, CK-7, CEA-monoclonal and negative for Calretinin, CD 10 and CK-20 supporting the

(MR # [REDACTED]) Printed by [REDACTED]

[page 4 of 4]
[REDACTED] (MR # [REDACTED])

diagnosis.

C. Endometrium, curettings:

- Abundant blood with small fragments of
proliferative-type endometrium with focal stromal
breakdown.

Accession #: [REDACTED]

- Negative for malignancy.

IMMUNOHISTOCHEMISTRY DISCLAIMER: This test was developed
and its performance characteristics determined by [REDACTED]
[REDACTED] It has not been cleared or
approved by the U.S. Food and Drug Administration. The FDA
has determined that such clearance or approval is not
necessary. By placing the electronic signature on this
report, the pathologist certifies that all positive and
negative immunohistochemistry controls were reviewed and
approved.

[REDACTED] MD [REDACTED]
(Electronically signed by)
Verified: [REDACTED]

Reviewed:

This case was reviewed at the [REDACTED]
on [REDACTED]

[REDACTED] (MR # [REDACTED])

Printed by [REDACTED]

Source: NCI Genomic Data Commons file 1bcbe908-9784-4dc1-b6e1-e50ee391eacf (TCGA-C5-A7CM.E9F95E79-28C9-4AA3-B0D7-02B00447B321.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).